Gene-level copy-number profile of tumor specimen TCGA-A6-3809-01B from TCGA case TCGA-A6-3809, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A6-3809-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ca3428c3-9390-45df-b348-baac03d34360.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-3809-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/865355d7-39cb-4d36-9a40-65c257a0da7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 68; copy number 2: 59,402; copy number 3: 565; copy number 4: 39; copy number 5: 138; copy number 6: 19; copy number 7: 15; copy number 8: 4; copy number 9: 1; copy number 10: 1; copy number 11: 1; copy number 13: 1; copy number 14: 1; copy number 16: 3; copy number 19: 1; copy number 20: 1; copy number 21: 2; copy number 23: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-3809-01A-01D-A274-01): tumor purity 0.62, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,908,098–21,908,580, 1 gene: AL590556.1.
- chr3:44,555,193–44,594,173, 1 gene (within-gene range 0–2): ZKSCAN7.
- chr3:44,578,223–44,599,694, 2 genes: ZNF660, MPRIPP1.
- chr3:93,843,764–93,843,862, 1 gene: RNU6-488P.
- chr4:182,548,659–182,548,779, 1 gene: RNU2-34P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 184 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,709,392–43,743,741, 3 genes, copy number 7 (within-gene range 2–7): ST3GAL3-AS1, U6, AL451062.1.
- chr1:64,941,979–64,942,365, 1 gene, copy number 11: AL606517.1.
- chr1:179,220,938–179,222,125, 1 gene, copy number 23: AL512326.3.
- chr2:20,155,618–20,156,057, 1 gene, copy number 19: RPS16P2.
- chr2:74,628,328–74,683,853, 2 genes, copy number 5 (within-gene range 2–5): TVP23BP2, SEMA4F.
- chr2:97,113,153–97,589,965, 15 genes, copy number 6: ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1.
- chr3:130,111,669–130,201,336, 2 genes, copy number 6 (within-gene range 2–6): LINC02021, ENPP7P3.
- chr3:179,169,083–179,169,210, 1 gene, copy number 6: AC076966.1.
- chr5:20,158,662–20,158,956, 1 gene, copy number 5: AC093303.1.
- chr5:179,629,151–179,652,457, 3 genes, copy number 7: Metazoa_SRP, C5orf60, AC136604.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 8: AC128676.1.
- chr7:72,924,418–72,925,125, 1 gene, copy number 16: AC211476.2.
- chr8:41,803,349–41,803,450, 1 gene, copy number 10: Y_RNA.
- chr10:2,936,021–2,936,441, 1 gene, copy number 20: AC026396.1.
- chr10:59,176,643–59,247,774, 1 gene, copy number 7 (within-gene range 2–7): PHYHIPL.
- chr12:32,396,050–32,396,147, 1 gene, copy number 5: Y_RNA.
- chr12:95,438,737–95,467,861, 2 genes, copy number 5: RNU6-735P, AC018475.1.
- chr12:97,491,909–97,496,057, 5 genes, copy number 7: MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1.
- chr12:131,436,447–131,458,324, 3 genes, copy number 5: AC073578.4, AC073578.2, AC073578.5.
- chr13:48,316,863–48,328,564, 2 genes, copy number 16: PPP1R26P1, PCNPP5.
- chr13:55,062,945–55,161,490, 2 genes, copy number 5 (within-gene range 2–5): LINC02335, AL139038.1.
- chr14:70,906,657–70,907,111, 1 gene, copy number 14: AC004825.2.
- chr14:105,836,765–106,481,706, 120 genes, copy number 5 (broad region; genes not listed).
- chr14:106,489,345–106,489,756, 1 gene, copy number 5: IGHVIV-44-1.
- chr15:101,875,964–101,933,350, 5 genes, copy number 5: OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr16:53,487,607–53,489,943, 1 gene, copy number 9 (within-gene range 2–9): AC007342.7.
- chr17:41,265,339–41,276,697, 3 genes, copy number 7: KRTAP9-6, KRTAP9-11P, KRTAP9-7.
- chr18:34,737,795–34,767,663, 1 gene, copy number 5: AC022601.1.
- chr20:1,561,385–1,620,061, 2 genes, copy number 21 (within-gene range 2–21): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
